Somatic mutation profile of tumor specimen 1105240 (aliquot 7316UP-2310-1105240) from CPTAC case C761370, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105240: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 53dd3f88-be71-483e-b837-a841f56beb78.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105210 (Blood Derived Normal), aliquot 7316UP-1848-1105210; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/edc707c5-4c55-45f5-a161-a291733bcc65

The open-access MAF lists 44 somatic variants for this specimen: 26 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 15, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD18B | c.1667G>A p.R556H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs544682999, COSV52094798; called by muse, mutect2, varscan2
- C1orf158 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs750241731, COSV55346815, COSV55347143, COSV99847419; called by muse, mutect2
- CNTNAP4 | c.2540C>T p.P847L | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1170966719, COSV56669709; called by muse, mutect2
- DNAH7 | c.5575G>A p.A1859T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1226573563; called by muse, mutect2
- KCNH5 | c.1892G>A p.R631Q | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs970741080, COSV59759638; called by muse, mutect2
- OR52N5 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs766003251, COSV57699403; called by muse, mutect2
- OR5D18 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs770766899, COSV100450944; called by muse, mutect2
- PCDHGA7 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 18/281 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV53927246; called by muse, mutect2
- SALL4 | c.2465G>A p.R822Q | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.978); catalogued as rs754932119; called by muse, mutect2
- SHOX | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs758706054, COSV61860840; called by muse, mutect2
- SULT2B1 | c.857C>T p.T286M (on ENST00000201586 / NM_177973.2; = p.T271M on NM_004605.2) | Missense Mutation (SNP) | VAF 29/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750776892; called by muse, mutect2
- TTLL7 | c.2317C>T p.R773C | Missense Mutation (SNP) | VAF 10/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1191689608, COSV53081769; called by muse, mutect2
- WNT2 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.124); catalogued as rs779778873, COSV55410380; called by muse, mutect2
- ZNF536 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100835448; called by muse, mutect2, varscan2
- ARNT | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- CHAT | c.692A>G p.Q231R | Missense Mutation (SNP) | VAF 41/490 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); called by muse, mutect2
- DNAH5 | c.3080T>A p.L1027Q | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FOXB2 | c.1195T>C p.S399P | Missense Mutation (SNP) | VAF 26/455 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- HOXA1 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 29/378 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAGEE2 | c.229A>G p.R77G | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.035); called by muse, mutect2
- RPL5 | c.115C>T p.Q39* | Nonsense Mutation (SNP) | VAF 17/300 reads (6%) | called by muse, mutect2
- SOS2 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SRSF4 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 45/516 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- THSD7A | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); called by muse, mutect2
- TSC22D2 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- USH2A | c.7760T>C p.V2587A | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2
- CFAP20DC | c.1242G>A p.Q414= (on ENST00000482387 / NM_001351530.2; = p.Q289= on NM_198463.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/156 reads (14%) | called by muse, mutect2, varscan2
- FREM1 | c.4113T>G p.L1371= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as rs1284219939; called by muse, mutect2
- GPR156 | c.1443T>C p.D481= | Silent (SNP) | VAF 18/237 reads (8%) | called by muse, mutect2
- NACA2 | c.144A>G p.T48= | Silent (SNP) | VAF 42/552 reads (8%) | called by muse, mutect2
- NDRG1 | c.705C>T p.R235= | Silent (SNP) | VAF 38/590 reads (6%) | catalogued as rs528436514; called by muse, mutect2
- NEIL3 | c.1062A>G p.E354= | Silent (SNP) | VAF 7/147 reads (5%) | called by muse, mutect2
- PCDHA2 | c.1527G>A p.S509= | Silent (SNP) | VAF 62/780 reads (8%) | catalogued as COSV65370386; called by muse, mutect2
- PCDHA7 | c.1509G>A p.A503= | Silent (SNP) | VAF 77/682 reads (11%) | catalogued as COSV65347773; called by muse, mutect2, varscan2
- PCDHB9 | c.1629C>T p.S543= | Silent (SNP) | VAF 81/879 reads (9%) | catalogued as rs373422120, COSV53379717; called by muse, mutect2
- RREB1 | c.2052C>T p.A684= | Silent (SNP) | VAF 5/91 reads (5%) | catalogued as rs916815830, COSV58561842; called by muse, mutect2
- SGCE | c.801G>A p.P267= (on ENST00000647096; = p.P231= on NM_003919.3) | Silent (SNP) | VAF 20/318 reads (6%) | catalogued as rs757206832, COSV56018366; ClinVar: likely benign; called by muse, mutect2
- SPON1 | c.1653C>T p.N551= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as rs367978833; called by muse, mutect2
- TICRR | c.2925C>T p.I975= | Silent (SNP) | VAF 14/214 reads (7%) | catalogued as rs1230055835; called by muse, mutect2
- TMEM132C | c.2835C>T p.C945= | Silent (SNP) | VAF 10/240 reads (4%) | catalogued as rs1447071874, COSV59422192; called by muse, mutect2
- TOGARAM1 | c.3747A>G p.L1249= | Silent (SNP) | VAF 16/216 reads (7%) | catalogued as COSV63890380; called by muse, mutect2
- DNMBP | c.2261-21239A>C | Intron (SNP) | VAF 9/92 reads (10%) | called by muse, mutect2, varscan2
- PCDHA1 | c.2394+15C>T | Intron (SNP) | VAF 6/46 reads (13%) | catalogued as rs782065488, COSV65374043, COSV65377107; called by muse, mutect2
- SEPTIN9 | c.*588T>C | 3'UTR (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
